Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7242, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7242-01A (Primary Tumor).

[page 1 of 4]
Collected:

Accession:

Received:

Case type: Surgical Case

***** **MODIFIED REPORT - REVIEW ADDENDUM SECTION** *****

DIAGNOSIS

(A) TOTAL LARYNGECTOMY, BILATERAL NECK DISSECTIONS, LEVEL II, III AND IV AND RIGHT HEMITHYROIDECTOMY:

INVASIVE SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED, 2.2 CM INVOLVING RIGHT TRANSGLOTIC REGION (SEE COMMENT)

Tumor Features:

Gross: Exophytic

Size: 2.2 cm in largest dimension

Invasion: Present, depth 1.6 cm

Tumor Border: Infiltrative with thick cords > 4 cells

Perineural Invasion: Absent

Vascular Invasion: Absent

Bone / Cartilage Invasion: Pending Decalcification (see addendum)

Lymphocyte Infiltration: Mild

Right neck dissection

No tumor present in 16 Lymph Nodes.

Level II:

Positive Nodes = 0

Total Nodes = 6

Level III:

Positive Nodes = 0

Total Nodes = 7

Level IV:

Positive Nodes = 0

Total Nodes = 3

Left neck dissection

No tumor present in 27 Lymph Nodes.

Level II:

Positive Nodes = 0

Total Nodes = 10

Level III:

Positive Nodes = 0

Total Nodes = 7

Level IV:

Positive Nodes = 0

Total Nodes = 10

[page 2 of 4]
[REDACTED]

Thyroid, no tumor present

(B) POSTERIOR CRICOID:

Squamous mucosa, negative for tumor

(C) RIGHT LATERAL PHARYNX:

Squamous mucosa, negative for tumor

(D) LEFT LATERAL PHARYNX:

Squamous mucosa, negative for tumor

COMMENT

(A) The balance of right transglottic region with subjacent cartilage and bone is pending decalcification (A5-A9). The results will be reported in a separate addendum.

[REDACTED]

GROSS DESCRIPTION

(A) TOTAL LARYNGECTOMY, BILATERAL NECK DISSECTIONS, LEVEL II, III AND IV AND RIGHT HEMITHYROIDECTOMY - A total laryngectomy specimen (7.8 x 4.0 x 4.0 cm) with attached soft tissue and muscle (8.0 x 6.0 x 1.2 cm and right thyroid (3.0 x 3.0 x 2.1 cm). There is a polypoid mass in the right transglottic region measuring 2.2 x 1.9 cm and 1.6 cm in depth. The tumor has homogeneous yellow-tan cut surface with no grossly hemorrhage or necrosis. The mass abuts the thyroid cartilage and it is 3.0 cm to the tracheal cartilage resection margin. The left transglottic mucosa is grossly uninvolved by the mass. Sectioning of the right thyroid reveals spongy, brownish mucosa with no lesion grossly seen. Multiple lymph nodes identified in the neck resection soft tissue and are entirely submitted.

Normal and tumor are submitted for Tumor Bank.

SECTION CODE: A1, tracheal margin; A2, A3, random section of right thyroid; A4, left transglottic region; A5-A9, right transglottic mass submitted from right to left (A5-A8, submitted after decalcification); A10-A11, left level II, one possible node bisected in each section; A12-A13, left level II possible lymph nodes, four per each section; A14, left level III, four possible nodes; A15, left level III, five possible lymph nodes [REDACTED]

A16-A18, left level 4, five possible nodes per section; A19, left level 4, four possible nodes; A20, right level 2, one possible node bisected; A21, right level 2, three possible nodes; A22, right level 2, four possible nodes; A23-A25, right level 3, five possible nodes in each section; A26, right level 4, one possible node; A27, right level 4, one possible node, bisected; A28, right level 4, one possible node bisected; A29, muscle. [REDACTED]

(B) POSTERIOR CRICOID - Received is a pink soft tissue (2 x 0.8 x 0.5), entirely submitted for frozen in B.

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(C) RIGHT LATERAL PHARYNX - Received is a pink soft tissue (2.4 x 0.9 x 0.5), entirely submitted for frozen in C.

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(D) LEFT LATERAL PHARYNX - Received is a pink soft tissue (2 x 0.8 x 0.5), entirely submitted for frozen in D.

*FS/DX: NO TUMOR PRESENT. [REDACTED]

[page 3 of 4]
CLINICAL HISTORY

Squamous cell carcinoma, larynx.

SNOMED CODES

T-C4200, T-24100, M-80706, M-80703, M-43000,

Entire report and diagnosis completed by

[page 4 of 4]
ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(A) TOTAL LARYNGECTOMY, BILATERAL NECK DISSECTION, LEVELS II, III, IV AND RIGHT HEMITHYROIDECTOMY:
INVASIVE SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED, ABUTTING CARTILAGE AND BONE.

Entire report and diagnosis completed by:

Surgical Pathology Report		Page 4 of 4
File under: Pathology		

Source: NCI Genomic Data Commons file a9d17564-6e1b-43d0-b521-f25da73a34be (TCGA-CV-7242.01B0A063-11BB-4CBD-9605-50F37CBB71AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).